Somatic mutation profile of tumor specimen TCGA-AQ-A0Y5-01A (aliquot TCGA-AQ-A0Y5-01A-11D-A14K-09) from TCGA case TCGA-AQ-A0Y5, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,793 days).
Specimen TCGA-AQ-A0Y5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1a5661df-2a2a-43ad-80fc-1d469d0d9768.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AQ-A0Y5-10A (Blood Derived Normal), aliquot TCGA-AQ-A0Y5-10A-01D-A17G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/402b8672-9f30-4de3-ac56-1a2f2607abd3

The open-access MAF lists 57 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 3, Splice Site 2, Intron 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGL | c.2546+2T>C p.X849_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV54053562; called by muse, mutect2, varscan2
- AP2A1 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100756393; called by muse, mutect2
- CACNA1D | c.4582T>A p.C1528S (on ENST00000350061 / NM_001128840.3; = p.C1548S on NM_000720.4) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV55450014; called by muse, mutect2, varscan2
- CCSER1 | c.1917G>C p.K639N | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61437798; called by muse, mutect2, varscan2
- CDH13 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as rs751441653, COSV51813549, COSV99224247; called by muse, mutect2
- CKAP2 | c.1914G>T p.L638F (on ENST00000378037 / NM_001098525.2; = p.L637F on NM_018204.5) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51622621; called by muse, mutect2, varscan2
- CNST | c.909G>C p.K303N | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV63621915; called by muse, mutect2, varscan2
- CUL1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as COSV57389325; called by muse, mutect2, varscan2
- DNMT1 | c.964_966del p.E322del | In Frame Del (DEL) | VAF 4/39 reads (10%) | catalogued as rs1362912301; called by pindel, varscan2
- EGFLAM | c.2696G>C p.G899A (on ENST00000354891 / NM_001205301.2; = p.G891A on NM_152403.4) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380505; called by muse, mutect2
- EPN1 | c.1133C>G p.P378R (on ENST00000270460 / NM_001321263.1; = p.P353R on NM_013333.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV50038517, COSV50038711; called by muse, mutect2
- EPS8 | c.2056C>T p.Q686* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as COSV55531762; called by muse, mutect2, varscan2
- FKBP8 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); catalogued as rs760604410, COSV55892698; called by muse, mutect2
- GBP5 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.286); catalogued as rs763884452, COSV58593093; called by muse, mutect2, varscan2
- GUCY2C | c.690G>T p.K230N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV53792533, COSV99663865; called by muse, mutect2
- HMOX2 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.741); catalogued as COSV54860511, COSV99566646; called by muse, mutect2, varscan2
- INTS14 | c.1001G>A p.G334E (on ENST00000313182 / NM_001366360.2; = p.G255E on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57527394; called by muse, mutect2, varscan2
- LAMA2 | c.8356C>T p.R2786C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs199806512, COSV70344186; called by muse, mutect2, varscan2
- LOXL2 | c.447G>C p.K149N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV66691820; called by muse, mutect2, varscan2
- LRP8 | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs758211330, COSV60097457; called by muse, mutect2, varscan2
- MYH6 | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as rs759408374, COSV62447730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4P4 | c.932T>A p.L311H | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.2); catalogued as COSV100111794; called by muse, mutect2, varscan2
- OR5K2 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs768818875, COSV71143244, COSV71143538; called by muse, mutect2, varscan2
- PPRC1 | c.830A>C p.H277P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.454); catalogued as COSV53385956; called by muse, mutect2, varscan2
- PTDSS2 | c.1069G>A p.V357M | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs777043477, COSV57278523; called by muse, mutect2, varscan2
- RAB11A | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); catalogued as COSV56042016; called by muse, mutect2, varscan2
- RALY | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.494); catalogued as rs768865097, COSV55781719; called by muse, mutect2, varscan2
- RYR3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 31/267 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs749097866, COSV66793506; called by muse, mutect2, varscan2
- SLC22A1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.017); catalogued as rs535669545, COSV61452658; called by muse, mutect2, varscan2
- SLC22A6 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64560322; called by muse, mutect2, varscan2
- SLC9A9 | c.717G>C p.E239D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100342295, COSV57229350, COSV57243002; called by muse, mutect2
- THSD7A | c.1434T>A p.S478R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.04); catalogued as COSV70266031; called by muse, mutect2, varscan2
- TINAG | c.994C>T p.R332W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767247771, COSV52506849; called by muse, mutect2, varscan2
- TMEM71 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs542588923, COSV63457729; called by muse, mutect2, varscan2
- TNS3 | c.2197C>G p.P733A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.039); catalogued as COSV60792403; called by muse, mutect2, varscan2
- TUT4 | c.4721G>A p.R1574Q | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV57111480; called by muse, mutect2, varscan2
- UBQLN3 | c.1207A>C p.I403L | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV61164495; called by muse, mutect2, varscan2
- ZFP69 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.843); catalogued as rs752437339, COSV65529111; called by muse, mutect2, varscan2
- ZMYM6 | c.3518C>G p.S1173* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100593269; called by muse, mutect2
- PARP8 | c.1977+2T>A p.X659_splice | Splice Site (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- TBC1D4 | c.1583_1607del p.T528Ifs*24 | Frame Shift Del (DEL) | VAF 11/62 reads (18%) | called by mutect2, pindel*
- ADORA2A | c.1107G>A p.G369= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs200477483; called by muse, varscan2
- B4GALNT1 | c.1440G>A p.V480= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV100247233; called by muse, mutect2
- CACNA1C | c.1071C>T p.F357= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV59720020; called by muse, mutect2, varscan2
- CACNA1S | c.2385C>A p.I795= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs200730765, COSV62940430; called by muse, mutect2, varscan2
- DNAH1 | c.1020G>T p.G340= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV70229960; called by muse, mutect2, varscan2
- DSCAML1 | c.4911A>G p.P1637= (on ENST00000321322; = p.P1577= on NM_020693.4) | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV58392644; called by muse, mutect2, varscan2
- OR2L13 | c.225C>A p.T75= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV63554298; called by muse, mutect2, varscan2
- PCDHGB1 | c.258G>A p.R86= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs758756356, COSV53963640; called by muse, mutect2, varscan2
- RBFOX1 | c.954C>T p.Y318= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs182244522, COSV100299252, COSV60962133; called by muse, mutect2, varscan2
- RHPN2 | c.915C>T p.F305= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV54277069; called by muse, mutect2, varscan2
- THSD7B | c.3435C>T p.C1145= (on ENST00000272643; = p.C1143= on NM_001316349.2) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs775388843, COSV55690072, COSV55711654; called by mutect2, varscan2
- VWA3A | c.591C>T p.I197= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs776374263, COSV67012751; called by muse, mutect2, varscan2
- ZBBX | c.492A>G p.K164= | Silent (SNP) | VAF 17/94 reads (18%) | catalogued as rs376791064; called by muse, mutect2, varscan2
- ZNF281 | c.1110C>G p.V370= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV54167479, COSV99663976; called by muse, mutect2, varscan2
- WDR82 | c.260-1298C>G | Intron (SNP) | VAF 14/36 reads (39%) | catalogued as COSV56601911; called by muse, mutect2, varscan2
